Gene-level copy-number profile of tumor specimen TCGA-DM-A28A-01A from TCGA case TCGA-DM-A28A, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 78.9 years (28,833 days).
Specimen TCGA-DM-A28A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.a7580bd6-b2f2-4df3-a44b-d00398c0eda2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DM-A28A-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f2fc3d0-a942-493d-8168-4f9f9b5abbd3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 6; copy number 2: 12,850; copy number 3: 3,312; copy number 4: 38,409; copy number 5: 1,887; copy number 6: 2,243; copy number 7: 601; copy number 8: 7; copy number 9: 74; copy number 11: 273; copy number 13: 147.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DM-A28A-01A-21D-A16U-01): tumor purity 0.87, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 494 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:208,885,755–208,920,664, 2 genes, copy number 11: AC109824.1, RNA5SP117.
- chr9:85,492,579–86,488,607, 20 genes, copy number 11: STK33P1, AGTPBP1, AL353743.4, AL157882.1, AL353743.2, AL353743.1, PHBP7, AL353743.3, NAA35, GOLM1, AL161447.2, AL161447.1, C9orf153, AL137849.1, RN7SKP264, ISCA1, TUT7, AL353678.1, AL158828.1, RNU2-36P.
- chr9:88,990,863–89,821,753, 14 genes, copy number 9 (within-gene range 6–9): S1PR3, SHC3, AL353150.1, CKS2, MIR3153, SECISBP2, SEMA4D, PA2G4P6, AL590233.1, AL161910.1, GADD45G, UNQ6494, BX470209.2, BX470209.1.
- chr9:94,726,604–97,068,628, 60 genes, copy number 9 (within-gene range 5–9): AOPEP, MIR2278, AL807757.1, AL807757.2, AL353768.1, AL353768.2, MIR6081, MIR23B, MIR27B, MIR3074, MIR24-1, FANCC, AL354893.2, AL354893.1, RNA5SP288, AL157384.1, AL161729.3, MT1P1, PTCH1, AL161729.2, AL161729.1, AL161729.4, AL392185.1, AL354861.2, AL354861.1, LINC00476, AL354861.3, RNU2-46P, ERCC6L2, RNA5SP289, AL161454.1, LINC00092, AL449403.1, Y_RNA, AL449403.2, AL449403.3, EIF4BP3, HSD17B3, AL160269.1, HSD17B3-AS1, RNU6-1160P, SLC35D2, ZNF367, NSA2P7, AL133477.1, AL133477.2, HABP4, CDC14B, PRXL2C, AL589843.1, AL589843.2, ZNF510, ZNF782, MFSD14C, PTMAP11, AL158827.1, NUTM2G, YRDCP2, CTSV, TCEA1P1.
- chr20:43,894,720–61,083,750, 398 genes, copy number 11–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
